Somatic mutation profile of tumor specimen 0DCM1N from CCDI case PBBMPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 14.6 years (5,350 days).
Specimen 0DCM1N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce9cd214-2cf7-4ac6-b5ba-492cc4f88d26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCM1C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4918dea9-e408-4dda-bd24-4b41ab0db160

The open-access MAF lists 66 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Intron 5, Nonsense Mutation 3, 5'UTR 2, 3'UTR 2, Splice Site 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 326/710 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 582/716 reads (81%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- USH1C | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 52/707 reads (7%) | catalogued as rs377145777, CM074628; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTSL3 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 140/1300 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs200618255; called by muse, mutect2, varscan2
- ALOX5 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 521/786 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs767991624, COSV65554890; called by muse, mutect2, varscan2
- ATP2B2 | c.3506C>T p.S1169L (on ENST00000352432; = p.S1135L on NM_001330611.3) | Missense Mutation (SNP) | VAF 77/649 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.228); catalogued as rs781524123; called by muse, mutect2, varscan2
- CADPS | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 243/1021 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs776247631, COSV51871967; called by muse, mutect2, varscan2
- CLK2 | c.1227-6C>G | Splice Region (SNP) | VAF 65/497 reads (13%) | catalogued as rs911861028; called by muse, mutect2, varscan2
- CMYA5 | c.10052G>A p.R3351H | Missense Mutation (SNP) | VAF 175/747 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs150128179; called by muse, mutect2, varscan2
- CNBP | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 24/660 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.112); catalogued as COSV69655021; called by muse, mutect2
- DOCK10 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 75/744 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371764118; called by muse, mutect2, varscan2
- DSCAM | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 112/1266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760671095, COSV68028019; called by muse, mutect2
- FDXR | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 79/763 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53125159; called by muse, mutect2, varscan2
- GUCY2D | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 79/775 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as rs372005126; called by muse, mutect2, varscan2
- IL36RN | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.224); catalogued as rs776622427, COSV61010664; called by muse, mutect2
- ING4 | c.722G>A p.R241H (on ENST00000396807 / NM_001127582.2; = p.R240H on NM_016162.4) | Missense Mutation (SNP) | VAF 190/528 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751519940; called by muse, mutect2, varscan2
- KLK15 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 46/479 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs139927076, COSV56826391; called by muse, mutect2
- LGALS9B | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 136/1126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751381320, COSV99048305; called by muse, mutect2, varscan2
- MMP15 | c.1164+1G>A p.X388_splice | Splice Site (SNP) | VAF 171/458 reads (37%) | catalogued as COSV54678648; called by muse, mutect2, varscan2
- MYH14 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 88/1065 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746502994, COSV51823084; called by muse, mutect2
- NGFR | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 136/547 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV50805358; called by muse, mutect2, varscan2
- PIK3CG | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 299/611 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs752602335, COSV63247110; called by muse, mutect2, varscan2
- PPP1R12C | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 153/667 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs763353251; called by muse, mutect2, varscan2
- RTTN | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 150/903 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV55340888; called by muse, mutect2, varscan2
- SPATA31D1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 162/2570 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs746379227; called by muse, mutect2
- SYNE1 | c.10597C>T p.R3533C (on ENST00000367255 / NM_182961.4; = p.R3540C on NM_033071.3) | Missense Mutation (SNP) | VAF 103/1234 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs776816480, COSV54937774; called by muse, mutect2
- TGM6 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 114/730 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1446647275; called by muse, mutect2, varscan2
- ATP2B1 | c.3514C>T p.P1172S | Missense Mutation (SNP) | VAF 712/1409 reads (51%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC17 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 68/662 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF3A | c.2927G>T p.R976M | Missense Mutation (SNP) | VAF 72/595 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- GABRB2 | c.1282A>T p.R428* (on ENST00000274547; = p.R390* on NM_000813.3) | Nonsense Mutation (SNP) | VAF 271/1206 reads (22%) | called by mutect2, varscan2
- GRIN2C | c.1675A>G p.M559V | Missense Mutation (SNP) | VAF 46/571 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); called by muse, mutect2
- KLK14 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 125/589 reads (21%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LAMA1 | c.9115T>A p.C3039S | Missense Mutation (SNP) | VAF 100/1274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MBD5 | c.2555G>C p.G852A | Missense Mutation (SNP) | VAF 580/1085 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCOLN3 | c.317A>T p.Y106F | Missense Mutation (SNP) | VAF 359/1485 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NCOR2 | c.2928+1G>A p.X976_splice | Splice Site (SNP) | VAF 175/340 reads (51%) | called by muse, mutect2, varscan2
- PEX5L | c.1571G>C p.S524T | Missense Mutation (SNP) | VAF 120/1506 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2
- POGLUT1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 172/1525 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB34 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 108/1497 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- RGPD4 | c.1576A>G p.T526A | Missense Mutation (SNP) | VAF 297/1235 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XDH | c.2673A>T p.K891N | Missense Mutation (SNP) | VAF 608/1122 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZC3HAV1 | c.2294C>G p.S765* | Nonsense Mutation (SNP) | VAF 128/1402 reads (9%) | called by muse, mutect2
- ZNF431 | c.702T>G p.C234W | Missense Mutation (SNP) | VAF 118/699 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF844 | c.995_996del p.S332Wfs*6 | Frame Shift Del (DEL) | VAF 137/745 reads (18%) | called by pindel, varscan2
- CERS1 | c.21G>A p.A7= | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- CSN2 | c.438C>A p.L146= | Silent (SNP) | VAF 98/1216 reads (8%) | catalogued as COSV100778833; called by muse, mutect2
- HMCN1 | c.8925C>T p.T2975= | Silent (SNP) | VAF 229/1106 reads (21%) | catalogued as rs768922365; called by muse, mutect2, varscan2
- KIAA1671 | c.4449G>A p.P1483= | Silent (SNP) | VAF 105/937 reads (11%) | catalogued as rs1178327065; called by muse, mutect2, varscan2
- OPLAH | c.3534C>T p.D1178= | Silent (SNP) | VAF 274/358 reads (77%) | catalogued as rs782415814; called by muse, mutect2, varscan2
- PPP3CA | c.447A>C p.G149= | Silent (SNP) | VAF 120/1231 reads (10%) | called by muse, mutect2, varscan2
- PRKACG | c.258C>T p.V86= | Silent (SNP) | VAF 84/1016 reads (8%) | called by muse, mutect2
- RYR3 | c.4788G>A p.K1596= | Silent (SNP) | VAF 73/695 reads (11%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.1719G>A p.A573= (on ENST00000291707 / NM_053003.4; = p.A455= on NM_033329.2) | Silent (SNP) | VAF 494/1230 reads (40%) | catalogued as rs1386183006, COSV99389587; called by muse, varscan2
- SLC34A2 | c.867C>T p.N289= | Silent (SNP) | VAF 126/2038 reads (6%) | catalogued as rs140631105; called by muse, mutect2
- SLC6A13 | c.516G>A p.L172= | Silent (SNP) | VAF 157/1576 reads (10%) | called by muse, mutect2
- XKR7 | c.1395C>T p.P465= | Silent (SNP) | VAF 129/344 reads (38%) | catalogued as rs923352369; called by muse, mutect2, varscan2
- ARL14 | c.-34A>C | 5'UTR (SNP) | VAF 204/345 reads (59%) | called by muse, mutect2
- CA2 | c.351+42A>G | Intron (SNP) | VAF 476/1001 reads (48%) | catalogued as rs754490432; called by muse, mutect2, varscan2
- CLEC12B | c.565-30G>A | Intron (SNP) | VAF 201/1058 reads (19%) | catalogued as rs370778199; called by muse, mutect2, varscan2
- EYS | c.1767-8131C>G | Intron (SNP) | VAF 40/109 reads (37%) | called by mutect2, varscan2
- GUK1 | c.-232C>G | 5'UTR (SNP) | VAF 24/196 reads (12%) | catalogued as rs1055783090; called by muse, mutect2, varscan2
- KATNIP | c.809-77T>G | Intron (SNP) | VAF 17/518 reads (3%) | called by muse, mutect2
- VWC2 | c.*27T>A | 3'UTR (SNP) | VAF 374/1040 reads (36%) | called by muse, mutect2, varscan2
- WDR62 | c.3220+66C>T | Intron (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
- ZNF165 | c.*6T>C | 3'UTR (SNP) | VAF 70/962 reads (7%) | called by muse, mutect2
